Somatic mutation profile of tumor specimen TCGA-B0-5080-01A (aliquot TCGA-B0-5080-01A-01D-1501-10) from TCGA case TCGA-B0-5080, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 63.1 years (23,052 days).
Specimen TCGA-B0-5080-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e89e49f8-44d7-49ab-a41c-64d9c9036181.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5080-11A (Solid Tissue Normal), aliquot TCGA-B0-5080-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df554c25-b0cf-43d2-a6a5-acdb8518c24f

The open-access MAF lists 67 somatic variants for this specimen: 51 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 15, Frame Shift Del 2, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC008397.2 | c.1311C>A p.N437K | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53209365; called by muse, mutect2, varscan2
- ADGRF1 | c.1949C>T p.T650M | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs766570587, COSV51947363; called by muse, mutect2, varscan2
- APOB | c.1078G>C p.D360H | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV51949771; called by muse, mutect2, varscan2
- CACHD1 | c.377A>T p.Q126L | Missense Mutation (SNP) | VAF 48/479 reads (10%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.954); catalogued as COSV51559158; called by muse, mutect2
- CDH5 | c.1289A>T p.E430V | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV58519602; called by muse, mutect2, varscan2
- CDH8 | c.1806C>G p.D602E | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as COSV54867141, COSV54895067; called by muse, mutect2
- CENPC | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1355504666, COSV56625908; called by muse, mutect2, varscan2
- CENPF | c.1088A>T p.K363I | Missense Mutation (SNP) | VAF 29/291 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65278558; called by muse, mutect2
- DDX20 | c.514T>C p.S172P | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs776966677, COSV63831563; called by mutect2, varscan2
- ECI2 | c.930G>C p.E310D (on ENST00000380118 / NM_206836.3; = p.E280D on NM_006117.2) | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as COSV60988684; called by muse, mutect2, varscan2
- FAM118A | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 21/106 reads (20%) | catalogued as COSV53419287; called by muse, varscan2
- FCRL4 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.54); catalogued as COSV54862700, COSV54865903, COSV99619349; called by muse, mutect2
- GABRR1 | c.223T>A p.S75T | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.05); catalogued as COSV65619196; called by muse, mutect2
- GLI3 | c.4705C>G p.L1569V | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67894172; called by muse, mutect2, varscan2
- GPR101 | c.1243T>A p.Y415N | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53240146; called by muse, mutect2, varscan2
- GRB10 | c.1777G>A p.A593T (on ENST00000398812; = p.A547T on NM_001001549.3) | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.279); catalogued as COSV60015684; called by muse, mutect2, varscan2
- HCFC1 | c.2143C>T p.P715S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.607); catalogued as COSV60076856; called by muse, mutect2
- HNRNPUL1 | c.2327C>G p.P776R | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.396); catalogued as COSV54191533; called by muse, varscan2
- KIF13B | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV73054672; called by muse, mutect2, varscan2
- KIF19 | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV63430450; called by muse, varscan2
- LRPPRC | c.906C>A p.D302E | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV53242548; called by muse, mutect2, varscan2
- LUC7L2 | c.788C>A p.S263* | Nonsense Mutation (SNP) | VAF 79/504 reads (16%) | catalogued as COSV54929795; called by muse, mutect2, varscan2
- MYBPC2 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as rs375154247; called by muse, mutect2, varscan2
- NDST3 | c.1151A>T p.H384L | Missense Mutation (SNP) | VAF 17/435 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56627632; called by muse, mutect2
- PCDH15 | c.3406G>T p.D1136Y | Missense Mutation (SNP) | VAF 48/484 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57372502, COSV57380811, COSV57404150; called by muse, varscan2
- PCDH15 | c.3405G>T p.Q1135H | Missense Mutation (SNP) | VAF 50/486 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV57380838; called by muse, varscan2
- PMS1 | c.2518A>G p.N840D | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs369909997; called by muse, mutect2, varscan2
- POLD1 | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); catalogued as rs778843530, COSV70954898; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRDM15 | c.2759A>T p.D920V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV54158775; called by muse, mutect2
- RRP12 | c.389C>A p.A130D | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59666070, COSV59671043; called by muse, mutect2, varscan2
- RRP12 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1032781002, COSV59671054; called by muse, mutect2, varscan2
- RTL3 | c.204G>T p.M68I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV58185629; called by muse, mutect2, varscan2
- SAMD14 | c.907T>C p.Y303H (on ENST00000330175 / NM_001257359.2; = p.Y331H on NM_174920.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV50304726; called by muse, mutect2
- SLC45A2 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs554113064, COSV56874201; called by muse, mutect2, varscan2
- STX19 | c.831A>C p.R277S | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV57401038; called by muse, mutect2, varscan2
- TCF20 | c.2293G>T p.D765Y | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV59495466; called by muse, mutect2, varscan2
- THSD7B | c.3337G>A p.D1113N (on ENST00000272643; = p.D1111N on NM_001316349.2) | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV55722167; called by muse, mutect2, varscan2
- TMEM50B | c.44G>A p.C15Y | Missense Mutation (SNP) | VAF 53/332 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV70279415; called by muse, mutect2, varscan2
- ULK2 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV64448032; called by muse, mutect2, varscan2
- USP15 | c.2793G>C p.Q931H (on ENST00000280377 / NM_001351159.2; = p.Q902H on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV54797800; called by muse, mutect2, varscan2
- USP8 | c.3177C>G p.H1059Q | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56168075; called by muse, mutect2, varscan2
- VN1R2 | c.708C>A p.S236R | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV59039498; called by muse, mutect2, varscan2
- WDFY3 | c.7540T>A p.S2514T | Missense Mutation (SNP) | VAF 47/303 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV55712253; called by muse, mutect2, varscan2
- ZNF14 | c.893A>G p.K298R | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as COSV100694157; called by muse, mutect2
- ZNF623 | c.1388A>G p.Y463C | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV71697332; called by muse, mutect2
- ZNF792 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV68694209; called by muse, mutect2, varscan2
- FNDC3B | c.1324del p.C442Vfs*30 | Frame Shift Del (DEL) | VAF 17/114 reads (15%) | called by mutect2, pindel, varscan2
- IQGAP2 | c.723del p.N241Kfs*4 | Frame Shift Del (DEL) | VAF 43/265 reads (16%) | called by mutect2, pindel, varscan2
- SUPT5H | c.3205C>A p.L1069I | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.138); called by muse, mutect2
- TADA2A | c.543T>G p.N181K | Missense Mutation (SNP) | VAF 98/614 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- UBE3D | c.456dup p.S153Ifs*8 | Frame Shift Ins (INS) | VAF 25/212 reads (12%) | called by mutect2, varscan2
- ACSM4 | c.354C>A p.A118= | Silent (SNP) | VAF 27/139 reads (19%) | catalogued as COSV68068200, COSV68069133; called by muse, mutect2, varscan2
- ADGRV1 | c.6891G>A p.G2297= | Silent (SNP) | VAF 29/189 reads (15%) | catalogued as COSV67993876; called by muse, mutect2, varscan2
- ARMC3 | c.1677T>A p.T559= | Silent (SNP) | VAF 22/387 reads (6%) | catalogued as COSV53066502; called by muse, mutect2
- C1QC | c.303C>A p.P101= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV65890037; called by muse, mutect2, varscan2
- DNAH3 | c.1791G>A p.Q597= | Silent (SNP) | VAF 14/382 reads (4%) | catalogued as COSV54546774; called by muse, mutect2
- FAM118A | c.633T>C p.T211= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as COSV53419278; called by muse, varscan2
- FAM227B | c.450C>T p.S150= | Silent (SNP) | VAF 16/223 reads (7%) | catalogued as COSV54818082; called by muse, mutect2
- GALNT2 | c.1290T>A p.L430= | Silent (SNP) | VAF 38/274 reads (14%) | catalogued as COSV64197185; called by muse, mutect2, varscan2
- PAPOLG | c.63T>C p.I21= | Silent (SNP) | VAF 52/340 reads (15%) | catalogued as COSV53185269; called by muse, varscan2
- PIRT | c.186C>T p.G62= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs555559126, COSV74119824; called by muse, mutect2, varscan2
- PTBP1 | c.1149C>T p.D383= (on ENST00000349038 / NM_031991.4; = p.D409= on NM_002819.5) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1163355304, COSV62461549; called by muse, mutect2, varscan2
- SIGLEC8 | c.1020C>T p.S340= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV58475551; called by muse, mutect2, varscan2
- SLC29A3 | c.915G>A p.T305= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs1046944911, COSV64384385, COSV64386051; called by mutect2, varscan2
- TMED7-TICAM2 | c.666G>A p.E222= | Silent (SNP) | VAF 20/329 reads (6%) | catalogued as COSV56696193; called by muse, mutect2
- TP63 | c.1657T>C p.L553= | Silent (SNP) | VAF 33/218 reads (15%) | catalogued as CM010361, COSV53212905, COSV53218952; called by muse, mutect2, varscan2
- MUCL3 | c.947-24C>T | Intron (SNP) | VAF 70/448 reads (16%) | catalogued as COSV58518703; called by muse, mutect2, varscan2
